Somatic mutation profile of tumor specimen MP2PRT-PASZLS-TMP1-A (aliquot MP2PRT-PASZLS-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASZLS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,107 days).
Specimen MP2PRT-PASZLS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7f33786-1923-4f71-9cdf-4f06edcbbbf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZLS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZLS-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/493a9a09-f5d9-4e4c-a134-4e391a49a978

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 62/334 reads (19%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 31/289 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/235 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.1551C>A p.F517L | Missense Mutation (SNP) | VAF 156/346 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as CM970797; called by muse, mutect2, varscan2
- FRAS1 | c.11548C>T p.R3850C | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239883966, COSV99351585; called by muse, mutect2, varscan2
- KANK1 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 43/452 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs751137284; called by muse, mutect2
- MATR3 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63078249; called by muse, varscan2
- SALL3 | c.3035G>A p.R1012Q | Missense Mutation (SNP) | VAF 79/527 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs150707152; called by muse, mutect2, varscan2
- STK32A | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 74/181 reads (41%) | catalogued as rs754820325, COSV60418139, COSV60419670; called by muse, mutect2, varscan2
- ZFAT | c.2906C>G p.T969R | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as rs777595729, COSV64739760; called by muse, mutect2, varscan2
- RBL2 | c.3373T>G p.L1125V | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- VRK2 | c.593A>T p.N198I | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- OR1M1 | c.96C>T p.F32= | Silent (SNP) | VAF 112/259 reads (43%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.246C>T p.D82= | Silent (SNP) | VAF 174/347 reads (50%) | catalogued as rs371192887; called by muse, mutect2, varscan2
